Gene-level copy-number profile of tumor specimen TCGA-HC-8261-01B from TCGA case TCGA-HC-8261, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 48.9 years (17,874 days).
Specimen TCGA-HC-8261-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.05a21de2-ea0f-47d0-b712-2f9e9741db60.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HC-8261-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate.
https://portal.gdc.cancer.gov/files/4ad852aa-b9e2-4341-ae5c-6b333876ceea

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,403; copy number 1: 371; copy number 2: 56,922; copy number 3: 549; copy number 4: 14; copy number 5: 2; copy number 6: 3; copy number 7: 1; copy number 8: 3; copy number 9: 2; copy number 10: 1; copy number 12: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HC-8261-01A-11D-2259-01): tumor purity 0.69, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:149,439,897–149,440,427, 1 gene: RPL17P13.
- chr3:46,712,115–46,812,574, 1 gene (within-gene range 0–2): AC109583.1.
- chr3:46,742,092–46,812,558, 2 genes (within-gene range 0–2): AC109583.4, AC109583.2.
- chr8:143,541,648–143,603,224, 11 genes (within-gene range 0–2): AC067930.9, AC067930.3, RN7SKP175, GSDMD, MROH6, AC067930.4, NAPRT, AC067930.5, AC067930.1, EEF1D, TIGD5.
- chr10:8,513,687–8,515,106, 1 gene: KRT8P37.
- chr10:110,257,064–110,257,843, 1 gene: AL360182.1.
- chr13:60,636,888–60,638,097, 1 gene: EIF4A1P6.
- chr17:44,596,346–44,597,344, 1 gene: AC091152.3.
- chr17:57,618,108–57,618,393, 1 gene: RN7SL449P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:156,441,157–156,446,905, 1 gene, copy number 10 (within-gene range 2–10): KCNAB1-AS1.
- chr5:29,795,938–29,796,268, 1 gene, copy number 8: AC108082.1.
- chr6:30,238,301–30,242,279, 1 gene, copy number 12: TRIM26BP.
- chr6:158,296,671–158,303,372, 1 gene, copy number 5: AL360169.3.
- chr6:166,098,111–166,099,589, 1 gene, copy number 9: AL627443.3.
- chr6:166,099,853–166,099,924, 1 gene, copy number 9: AL627443.2.
- chr7:144,000,320–144,008,793, 1 gene, copy number 5: OR6B1.
- chr10:4,201,141–4,243,912, 1 gene, copy number 7 (within-gene range 2–7): LINC00702.
- chr22:37,339,583–37,427,445, 1 gene, copy number 6 (within-gene range 2–6): ELFN2.
- chr22:37,367,960–37,427,479, 2 genes, copy number 6 (within-gene range 2–6): ELFN2, Z94160.2.

Autosomal genes at a single copy (total copy number 1): 336. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
